Somatic mutation profile of tumor specimen 0DDZ6R from CCDI case PBBMIP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 6.1 years (2,242 days).
Specimen 0DDZ6R: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a56f5a4f-086f-42c8-acf7-4c58df6f9f86.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDZ63 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc6fbc1b-ae38-4242-b912-2e0f5a607b6a

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXO41 | c.1427G>A p.R476Q | Missense Mutation (SNP) | VAF 85/204 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs200442553; called by muse, mutect2, varscan2
- SAGE1 | c.2432A>C p.N811T | Missense Mutation (SNP) | VAF 52/834 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); called by muse, mutect2
